Gene-level copy-number profile of tumor specimen TCGA-CV-5432-01A from TCGA case TCGA-CV-5432, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 68.5 years (25,006 days).
Specimen TCGA-CV-5432-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.4b8a8853-25ff-470e-83c4-bed22cfc82de.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-5432-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e3d901ac-c43d-4b09-92cb-1b5579b0cde8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 2: 4,777; copy number 3: 3,321; copy number 4: 15,994; copy number 5: 13,473; copy number 6: 7,453; copy number 7: 4,487; copy number 8: 2,932; copy number 9: 1,593; copy number 10: 848; copy number 11: 3,655; copy number 12: 20; copy number 13: 887; copy number 14: 26; copy number 15: 140; copy number 16: 11; copy number 17: 32; copy number 18: 18; copy number 19: 11; copy number 22: 3; copy number 23: 57; copy number 27: 12; copy number 29: 8; copy number 36: 10; copy number 42: 3; copy number 65: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-5432-01A-02D-1682-01): tumor purity 0.47, ploidy 5.35, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:178,602,664–179,083,977, 23 genes: CLK4, RN7SKP70, AC113348.3, AC113348.1, AC113348.2, ZNF354A, AACSP1, AC126915.2, AC126915.1, AC126915.3, ZNF354B, RNU1-39P, ZFP2, AC104117.1, PIGFP1, AC104117.5, ZNF454, AC104117.3, GRM6, AC104117.4, ZNF879, ZNF354C, AC104117.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 7,348 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:82,476,825–83,657,842, 12 genes, copy number 9: AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P.
- chr2:94,725,674–110,205,066, 365 genes, copy number 9–11 (broad region; genes not listed).
- chr3:68,731,766–72,550,552, 51 genes, copy number 9–11 (within-gene range 4–11): TAFA4, RNA5SP135, EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3, FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1, MITF, RN7SL418P, SAMMSON, AC139700.1, UQCRHP4, MDFIC2, AC104633.1, AC104633.2, COX6CP6, HMGB1P36, RNU6-281P, FOXP1, AC097634.4, FOXP1-AS1, MIR1284, AC097634.2, FOXP1-IT1, AC097634.3, AC097634.1, EIF4E3, GPR27, PROK2, AC096970.1, RN7SL271P, LINC00877, UBE2Q2P9, AC105265.2, AC105265.3, AC105265.1, CCDC137P, LINC00870, AC112219.2, AC112219.1, AC134508.2, AC134508.1, RYBP, AC104435.2.
- chr3:145,523,538–176,114,537, 452 genes, copy number 9–11 (broad region; genes not listed).
- chr3:176,515,103–176,515,151, 1 gene, copy number 9: MIR7977.
- chr5:31,400,497–33,298,066, 43 genes, copy number 11 (within-gene range 3–11): DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, AC008766.1, NPR3, AC025459.1, AC010343.3, LINC02120, AC034223.1, AC034223.2, AC010343.2, AC010343.1.
- chr6:38,675,925–41,381,832, 56 genes, copy number 10: GLO1, AL391415.1, DNAH8, RN7SL465P, AL035555.2, AL035555.1, DNAH8-AS1, AL034345.1, AL035690.1, GLP1R, SAYSD1, ANKRD18EP, KCNK5, KCNK17, KCNK16, KIF6, AL136087.1, E2F4P1, RNU1-54P, DAAM2, AL592158.1, DAAM2-AS1, MOCS1, TUBBP9, FO393411.1, AL139275.2, TDRG1, LINC00951, AL139275.1, LRFN2, RNU6-250P, AL359475.1, AL033380.1, AL583854.1, UNC5CL, OARD1, TSPO2, APOBEC2, NFYA, AL031778.1, ADCY10P1, TREML1, TREM2, TREML2, TREML3P, TREML4, RNA5SP207, TREML5P, AL391903.2, AL391903.3, TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2, AL136967.1.
- chr6:52,739,590–55,940,624, 66 genes, copy number 13–18 (broad region; genes not listed).
- chr6:60,281,444–62,611,327, 14 genes, copy number 9–22 (within-gene range 4–22): AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2.
- chr6:63,571,005–63,779,336, 5 genes, copy number 29: AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 29: AL354719.1, SCAT8, GCNT1P4.
- chr7:48,171,458–64,266,931, 299 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr7:126,378,970–159,233,377, 777 genes, copy number 9–11 (broad region; genes not listed).
- chr8:46,028,804–54,871,720, 134 genes, copy number 10 (broad region; genes not listed).
- chr9:31,505,280–36,124,455, 189 genes, copy number 11–16 (broad region; genes not listed).
- chr11:49,558,546–55,319,465, 50 genes, copy number 15–17 (within-gene range 6–17): AC136759.1, AC130364.1, AC130364.2, TRIM51FP, AP006587.5, AP006587.6, AP006587.4, AP006587.3, TRIM51DP, AP006587.1, AP006587.2, OR4A1P, OR4A49P, OR4A18P, OR4A19P, OR4R3P, OR4C13, OR4C12, OR4C48P, OR4C45, OR4C49P, GTF2IP11, AC109635.3, AC109635.6, AC109635.5, PHKG1P3, AC109635.4, AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1, OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P, TRIM48, AP005597.4, AP005597.3, AP005597.2, TRIM51HP, AP005597.1, OR4A11P.
- chr11:55,795,556–58,268,260, 151 genes, copy number 9–11 (broad region; genes not listed).
- chr12:66,767–34,046,417, 842 genes, copy number 13 (within-gene range 8–13) (broad region; genes not listed).
- chr12:37,575,587–39,170,880, 20 genes, copy number 12: ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1.
- chr13:18,467,172–19,865,048, 57 genes, copy number 11: ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3, RNU6-55P, RNU6-76P, SNX19P2, LINC00408, AL355516.1, PHF2P2, LINC00442, USP24P1, GTF2IP3, AL137001.1, AL137001.2, RNA5SP24, CENPIP1, AL139327.2, SMPD4P2, AL139327.3, TUBA3C, AL139327.1, PSPC1P1, ANKRD26P3, MRPL3P1, LINC00421, PARP4P2, CCNQP3, AL356259.1, SLC25A15P2, TPTE2, CYCSP32, MRPS31P2, ESRRAP1, LINC00350, CASC4P1, MPHOSPH8, PSPC1-AS2, PSPC1, RN7SL166P, ST6GALNAC4P1, ZMYM5, AL355001.1, AL355001.2.
- chr14:18,333,726–106,875,071, 2,285 genes, copy number 11–23 (broad region; genes not listed).
- chr15:79,845,150–80,951,776, 32 genes, copy number 9 (within-gene range 4–9): ST20-MTHFS, AC015871.4, AC015871.6, ST20, AC015871.7, AC015871.3, ST20-AS1, AC015871.8, AC015871.1, BCL2A1, AC015871.2, AC015871.5, AC092701.1, Metazoa_SRP, ZFAND6, FAH, AC087761.1, CTXND1, LINC00927, AC016705.2, ARNT2, AC016705.1, AC016705.3, AC108451.1, AC108451.2, MIR5572, RNU6-380P, ABHD17C, AC023302.1, AC023302.2, CEMIP, MIR549A.
- chr17:22,233,926–22,606,703, 23 genes, copy number 14: LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1.
- chr17:34,725,509–35,009,743, 6 genes, copy number 10–15: AC005552.1, AC022903.1, CCT6B, AC022903.2, ZNF830, LIG3.
- chr17:35,018,660–35,018,991, 1 gene, copy number 15: AC004223.4.
- chr17:37,140,611–37,163,139, 3 genes, copy number 42: AC244093.1, HMGB1P24, AC244093.2.
- chr17:39,461,486–39,997,959, 24 genes, copy number 36–65 (within-gene range 6–65): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3.
- chr18:47,390–15,330,282, 376 genes, copy number 9 (broad region; genes not listed).
- chr18:22,647,582–37,992,413, 227 genes, copy number 11–27 (broad region; genes not listed).
- chr21:10,328,411–24,547,942, 184 genes, copy number 10–19 (broad region; genes not listed).
- chr22:15,290,718–26,383,597, 600 genes, copy number 10–15 (within-gene range 6–15) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
